CCDI case PBBNSW — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/4c9bef6c-707e-4094-8066-e9ecb1aed8fe

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Glioblastoma: ICD-O-3 morphology code: 9440/3; Tissue or organ of origin: Frontal lobe; Age at diagnosis: 16.9 years (6,161 days).

Biospecimens (3 samples)
- Sample 0DDRN7: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DDRN8: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DDRN9: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
